CCDI case PBCDBM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasal cavity and middle ear.
https://portal.gdc.cancer.gov/cases/5779b173-26de-4924-8cc3-6cd27570e715

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Middle ear; Age at diagnosis: 1.7 years (613 days).

Biospecimens (3 samples)
- Sample 0DP0MT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP0N2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP0N5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
